MMRF case MMRF_1667 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/a150b23a-7000-4e62-8cfd-8bcbe22cba48

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 57 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 57.7 years (21,086 days); ISS stage: I; Days to last known disease status: 1,156 days (3.2 years); Days to last follow up: 1,156 days (3.2 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 106 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 107 days.
   Treatment given: Treatment type: Stem Cell Transplantation, Autologous; Regimen or line of therapy: First line of therapy; Days to treatment start: 149 days; Days to treatment end: 149 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 259 days; Days to treatment end: 474 days (1.3 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 475 days (1.3 years); Days to treatment end: 536 days (1.5 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -28 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 170 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.71 mg/dL; Immunoglobulin G 5.78 g/L; Immunoglobulin A 0.763 g/L; Immunoglobulin M 0.274 g/L; Beta 2 Microglobulin 2.8 µg/mL; Lactate Dehydrogenase 4.83 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 10.1 ×10⁹/L; Absolute Neutrophil 5.5 ×10⁹/L; Platelets 377 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.5 mmol/L; Albumin 46 g/L; Total Protein 7.5 g/dL; Glucose 7.7 mmol/L.
- Day 68 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.88 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.2 mg/dL; Immunoglobulin G 4.56 g/L; Immunoglobulin A 0.464 g/L; Immunoglobulin M 0.197 g/L; Beta 2 Microglobulin 1.9 µg/mL; Lactate Dehydrogenase 4.47 µkat/L; Hemoglobin 7.32 mmol/L; Leukocytes 3.4 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 201 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 42 g/L; Total Protein 6.5 g/dL; Glucose 6.55 mmol/L.
- Day 167 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.24 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 5.23 g/L; Immunoglobulin A 0.752 g/L; Immunoglobulin M 0.289 g/L; Lactate Dehydrogenase 6.37 µkat/L; Hemoglobin 8.12 mmol/L; Leukocytes 4.2 ×10⁹/L; Absolute Neutrophil 1.8 ×10⁹/L; Platelets 115 ×10⁹/L; Creatinine 52.2 µmol/L; Blood Urea Nitrogen 2.14 mmol/L; Calcium 2.38 mmol/L; Albumin 39 g/L; Total Protein 6.5 g/dL; Glucose 7.54 mmol/L.
- Day 259 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 11.3 g/L; Immunoglobulin A 0.612 g/L; Immunoglobulin M 0.408 g/L; Lactate Dehydrogenase 4.3 µkat/L; Hemoglobin 8.37 mmol/L; Leukocytes 4.9 ×10⁹/L; Absolute Neutrophil 2.3 ×10⁹/L; Platelets 295 ×10⁹/L; Creatinine 61.9 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 7.8 g/dL; Glucose 5.72 mmol/L.
- Day 316 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.6 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.5 mg/dL; Immunoglobulin G 0.456 g/L; Immunoglobulin A 0.721 g/L; Immunoglobulin M 8.75 g/L; Lactate Dehydrogenase 3.45 µkat/L; Hemoglobin 7.94 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.1 ×10⁹/L; Platelets 222 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.15 mmol/L; Albumin 42 g/L; Total Protein 6.7 g/dL; Glucose 6.66 mmol/L.
- Day 404 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.7 mg/dL; Immunoglobulin G 9.38 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.258 g/L; Lactate Dehydrogenase 3.05 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 5.6 ×10⁹/L; Absolute Neutrophil 2.6 ×10⁹/L; Platelets 240 ×10⁹/L; Creatinine 66.3 µmol/L; Blood Urea Nitrogen 3.57 mmol/L; Calcium 2.3 mmol/L; Albumin 43 g/L; Total Protein 7.1 g/dL; Glucose 7.21 mmol/L.
- Day 491 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.4 mg/dL; Immunoglobulin G 7.58 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.208 g/L; Lactate Dehydrogenase 3.25 µkat/L; Hemoglobin 7.69 mmol/L; Leukocytes 4.6 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 139 ×10⁹/L; Creatinine 67.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.28 mmol/L; Albumin 41 g/L; Total Protein 6.9 g/dL; Glucose 6.66 mmol/L.
- Day 610 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.2 mg/dL; Immunoglobulin G 8.08 g/L; Immunoglobulin A 1.06 g/L; Immunoglobulin M 0.408 g/L; Lactate Dehydrogenase 3.37 µkat/L; Hemoglobin 7.56 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 3 ×10⁹/L; Platelets 250 ×10⁹/L; Creatinine 63.6 µmol/L; Blood Urea Nitrogen 3.21 mmol/L; Calcium 2.28 mmol/L; Albumin 45 g/L; Total Protein 7 g/dL; Glucose 5.89 mmol/L.
- Day 694 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 8.42 g/L; Immunoglobulin A 1.03 g/L; Immunoglobulin M 0.257 g/L; Lactate Dehydrogenase 3.43 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 4.8 ×10⁹/L; Absolute Neutrophil 2.8 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 76.9 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.33 mmol/L; Albumin 42 g/L; Total Protein 7.1 g/dL; Glucose 6.49 mmol/L.
- Day 792 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.2 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 8.78 g/L; Immunoglobulin A 1.23 g/L; Immunoglobulin M 0.26 g/L; Lactate Dehydrogenase 3.52 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.7 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 223 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 47 g/L; Total Protein 7.7 g/dL; Glucose 5.39 mmol/L.
- Day 890 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.4 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.9 mg/dL; Immunoglobulin G 7.8 g/L; Immunoglobulin A 1.41 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 3.6 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 4.2 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.38 mmol/L; Albumin 46 g/L; Total Protein 7 g/dL; Glucose 7.92 mmol/L.
- Day 981 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 7.28 g/L; Immunoglobulin A 1.26 g/L; Immunoglobulin M 0.41 g/L; Lactate Dehydrogenase 3.95 µkat/L; Hemoglobin 8.43 mmol/L; Leukocytes 5.8 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 194 ×10⁹/L; Creatinine 68.1 µmol/L; Blood Urea Nitrogen 6.07 mmol/L; Calcium 2.33 mmol/L; Albumin 44 g/L; Total Protein 7 g/dL; Glucose 9.3 mmol/L.
- Day 1,072 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.19 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.8 mg/dL; Immunoglobulin G 7.39 g/L; Immunoglobulin A 1.31 g/L; Immunoglobulin M 0.33 g/L; Lactate Dehydrogenase 3.67 µkat/L; Hemoglobin 8.62 mmol/L; Leukocytes 10 ×10⁹/L; Absolute Neutrophil 7.3 ×10⁹/L; Platelets 225 ×10⁹/L; Creatinine 74.3 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.25 mmol/L; Albumin 46 g/L; Total Protein 7.4 g/dL; Glucose 6.22 mmol/L.
- Day 1,156 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.41 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1 mg/dL; Immunoglobulin G 8.67 g/L; Immunoglobulin A 1.51 g/L; Immunoglobulin M 0.4 g/L; Lactate Dehydrogenase 3.78 µkat/L; Hemoglobin 8.49 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2.9 ×10⁹/L; Platelets 230 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.35 mmol/L; Albumin 43 g/L; Total Protein 7.7 g/dL; Glucose 8.09 mmol/L.

Other clinical attributes
- Day -28: Weight: 65 kg; Height: 164 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1667_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -28 days.
- Sample MMRF_1667_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -28 days.
